Gene-level copy-number profile of tumor specimen ALCH-AEOY-TTP1-A from ALCHEMIST case ALCH-AEOY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 85.4 years (31,184 days).
Specimen ALCH-AEOY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ac5fa898-6b76-4872-b25b-42d4979f4152.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEOY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/50987e82-bb4d-4ef1-8348-8948b735eef8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 3,062; copy number 2: 55,787; copy number 3: 31; copy number 4: 20; copy number 5: 2; copy number 7: 1; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:239,068,817–239,085,926, 2 genes (within-gene range 0–2): MIR4440, MIR4441.
- chr7:23,450,658–23,450,722, 1 gene (within-gene range 0–2): RNU7-143P.
- chr19:43,353,686–43,379,123, 3 genes: CD177, AC005392.3, CD177P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,827,546, 2 genes, copy number 5: MIR5692C1, AC114296.1.
- chr13:112,313,467–112,321,758, 1 gene, copy number 8: LINC01043.
- chr16:3,144,015–3,149,963, 1 gene, copy number 7: CASP16P.

Autosomal genes at a single copy (total copy number 1): 227. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
